Surgical pathology report (de-identified scan), TCGA case TCGA-A4-8312, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-8312-01A (Primary Tumor).

Final Diagnosis

Mass, left kidney, wedge resection:

Papillary renal cell carcinoma, 1.5 cm in greatest dimension.

Fuhrman nuclear grade I/IV.

Tumor is limited to the wedge resection and the margins are free of involvement. Angiolymphatic invasion is not identified.

AJCC Pathologic Stage T1, Nx.

Renal cyst: Benign cyst with scant epithelial lining and no evidence of clear cells. Renal parenchyma underlying cyst wall shows sclerotic glomeruli.

Comment: The renal mass is small, 1.5 cm, and has a papillary appearance without typical foam cells

Slides reviewed with

Clinical Information

Left renal mass/left renal cyst.

Gross Description

"A, Left kidney mass." The specimen consists of a previously sectioned, previously inked fragment of kidney on reconstruction measures 2 x 1.5 x 1.2 cm. On the cut surface is an exposed tan friable mass measuring approximate 1.5 cm. The adjacent renal parenchyma is tan-gray and up to 0.4 cm thick. "A1-A3," fragments, all.

"B, Cyst wall." The specimen consists of a brown-tan collapsed thin-walled cyst measuring 2.3 x 1.2 cm. The cyst wall is less than 0.2 cm thick. "B," fragments, all.

Source: NCI Genomic Data Commons file 28cbbd8e-abc5-4bc8-a585-011d8f604ec0 (TCGA-A4-8312.99ECDA58-A015-41CA-ABC7-3E0E5FB01823.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).